Somatic mutation profile of tumor specimen TCGA-BS-A0UV-01A (aliquot TCGA-BS-A0UV-01A-11D-A10B-09) from TCGA case TCGA-BS-A0UV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.5 years (20,266 days).
Specimen TCGA-BS-A0UV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1bb249a-34b5-4c24-ba65-6347135a3357.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0UV-10A (Blood Derived Normal), aliquot TCGA-BS-A0UV-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/195ca5a2-9ca6-4ed5-bb1c-a363a6e93845

The open-access MAF lists 10,283 somatic variants for this specimen: 8,076 protein-altering or splice-affecting, 2,035 silent, 172 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,812, Silent 2,035, Nonsense Mutation 1,056, Splice Site 124, Intron 71, RNA 49, Splice Region 48, Frame Shift Ins 24, 3'UTR 24, 5'UTR 13, 3'Flank 10, Translation Start Site 6.

Variants (750 of 10,283; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3682G>T p.E1228* | Nonsense Mutation (SNP) | VAF 39/122 reads (32%) | catalogued as rs1057517869, COSV64671204; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772294884, CM067617, COSV55585728; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs376926391, CM082466, CM122251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764893806, CM1211185, COSV54693138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1S2 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 121/301 reads (40%) | catalogued as rs1555904878, COSV61306169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 53/143 reads (37%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAG3 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516881, CM1111351, COSV64841649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 54/141 reads (38%) | catalogued as rs896947430, COSV67502337; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDCA7 | c.821G>A p.R274H (on ENST00000347703 / NM_145810.3; = p.R353H on NM_031942.5) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370384522, CM157794; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CENPJ | c.2872C>T p.R958* | Nonsense Mutation (SNP) | VAF 73/198 reads (37%) | catalogued as rs749343808, COSV67882965; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CFP | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs132630259, CM950925, COSV55949739; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHEK2 | c.1090G>T p.E364* (on ENST00000382580 / NM_001005735.2; = p.E321* on NM_007194.4) | Nonsense Mutation (SNP) | VAF 41/207 reads (20%) | catalogued as rs1555915433, CM062510, COSV60415453; ClinVar: pathogenic; called by muse, varscan2
- CHM | c.116+1G>A p.X39_splice | Splice Site (SNP) | VAF 27/73 reads (37%) | catalogued as rs786204761, CS032061, CS1110030, CS166165, COSV62564414; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 11/131 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/68 reads (68%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, varscan2
- DMD | c.8608C>T p.R2870* | Nonsense Mutation (SNP) | VAF 82/223 reads (37%) | catalogued as rs398124074, CM013379, COSV58893120; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EYA4 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 95/260 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV62046082, COSV62054147; called by muse, mutect2, varscan2
- F9 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs387906477, COSV54378764; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4337-1G>T p.X1446_splice | Splice Site (SNP) | VAF 38/94 reads (40%) | catalogued as rs1555397424, CS075135, CS118010, COSV57309956; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FGFR2 | c.1645A>C p.N549H | Missense Mutation (SNP) | VAF 133/339 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519045, CM020140, COSV60640393, COSV60650624; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- GALT | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111033806, CM950559, CM993450, COSV58840206; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GFPT1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs922548333, COSV61946609; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLMN | c.743dup p.L248Ffs*14 | Frame Shift Ins (INS) | VAF 25/128 reads (20%) | catalogued as rs754756178; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GNAL | c.733C>T p.R245* (on ENST00000269162 / NM_001142339.3; = p.R322* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 60/164 reads (37%) | catalogued as rs1252185897, CM135135, COSV52323513; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HUWE1 | c.12559C>T p.R4187C | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121918527, CM081661, COSV99470874; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ICOS | c.58+1G>A p.X20_splice | Splice Site (SNP) | VAF 75/217 reads (35%) | catalogued as rs757598952, COSV57029287; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNJ11 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267607196, CM071810, COSV60594185; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2C | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 18/230 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1403418496, COSV51343575; called by muse, mutect2
- KPTN | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 28/99 reads (28%) | catalogued as rs761616995, COSV52637863; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as rs63749947, CD076834, CM076317, COSV51875855, COSV51883753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 45/174 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs3218713, CM910268, COSV62516493; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs782396605, COSV68683552; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NPC1 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376213990, CM032629; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OCRL | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 127/344 reads (37%) | catalogued as rs1556346316, CM990983, COSV63980169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 51/97 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 39/113 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 78/189 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RLIM | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1569309460, COSV60325321; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RSPH3 | c.595C>T p.R199* (on ENST00000252655; = p.R57* on NM_031924.8) | Nonsense Mutation (SNP) | VAF 74/183 reads (40%) | catalogued as rs760122351, COSV51921181; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.14581C>T p.R4861C | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs118192181, CM030712, COSV62111558; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SC5D | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | catalogued as rs1313359281, COSV50612637; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SDHD | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202198133, CM141636, COSV54777375; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 47/145 reads (32%) | hotspot (GDC flag); catalogued as COSV50993252; called by muse, mutect2, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2
- TF | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as rs121918680, CM024626, COSV53917909; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMC1 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 99/238 reads (42%) | catalogued as rs121908073, CM020519, COSV99918783; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 213/405 reads (53%) | catalogued as rs751517725, COSV60036110; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 153/218 reads (70%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780068, CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by mutect2, varscan2
- TRIO | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 57/134 reads (43%) | catalogued as rs1057516029, COSV60077909; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRIOBP | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as rs118204030, CD060673, CM067725, COSV100730667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.70546C>T p.R23516* (on ENST00000591111; = p.R16092* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 38/350 reads (11%) | catalogued as rs1553603394, COSV59899993; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TWNK | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs267606682, CM102249, COSV52966507; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 64/168 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, varscan2
- A1CF | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99255396; called by muse, mutect2
- A1CF | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV50957505; called by muse, mutect2, varscan2
- A2M | c.1477C>T p.L493F | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV100588497; called by muse, mutect2
- A2M | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV59383221; called by muse, mutect2, varscan2
- A2M | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59386709; called by muse, mutect2
- A2M | c.475A>T p.N159Y | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59383229; called by muse, mutect2, varscan2
- A2ML1 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55286086; called by muse, mutect2, varscan2
- A4GNT | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs775713265, COSV52628454; called by muse, mutect2, varscan2
- AADACL2 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 73/135 reads (54%) | catalogued as COSV62929608; called by muse, mutect2, varscan2
- AADACL2 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62929617; called by muse, mutect2, varscan2
- AADACL3 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60198185; called by muse, mutect2, varscan2
- AADACL4 | c.1147T>G p.F383V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV66105864; called by muse, mutect2, varscan2
- AARS2 | c.2636C>T p.S879L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs770826503, COSV55113435; called by muse, mutect2, varscan2
- AASDHPPT | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as COSV53788298; called by muse, varscan2
- AASDHPPT | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.676); catalogued as rs761620246, COSV53789640; called by muse, varscan2
- AASS | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62789002; called by muse, mutect2, varscan2
- AATF | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199725061; called by muse, mutect2, varscan2
- AATK | c.2950A>G p.S984G (on ENST00000326724 / NM_001080395.3; = p.S881G on NM_004920.2) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58364311; called by muse, mutect2, varscan2
- ABAT | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 55/145 reads (38%) | catalogued as rs1389255922, COSV51620481; called by muse, mutect2, varscan2
- ABCA1 | c.4231G>T p.D1411Y | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV66063954; called by muse, mutect2, varscan2
- ABCA10 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV52218518; called by muse, mutect2, varscan2
- ABCA12 | c.1682A>G p.N561S (on ENST00000272895 / NM_173076.3; = p.N243S on NM_015657.3) | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99788668; called by muse, mutect2
- ABCA12 | c.1423G>A p.E475K (on ENST00000272895 / NM_173076.3; = p.E157K on NM_015657.3) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs374329275; called by muse, varscan2
- ABCA12 | c.1324G>T p.E442* (on ENST00000272895 / NM_173076.3; = p.E124* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV55950013, COSV99791991; called by muse, varscan2
- ABCA12 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 59/156 reads (38%) | catalogued as COSV55950031; called by muse, mutect2, varscan2
- ABCA13 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1228654939, COSV70025944, COSV70026072; called by muse, mutect2, varscan2
- ABCA13 | c.8195G>A p.G2732E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.163); catalogued as COSV71283625; called by muse, mutect2, varscan2
- ABCA2 | c.3958G>A p.E1320K (on ENST00000614293; = p.E1290K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.08); catalogued as rs1206705940, COSV55797816; called by muse, mutect2, varscan2
- ABCA3 | c.2992C>T p.R998C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.892); catalogued as rs374123670, COSV100068720; called by muse, mutect2, varscan2
- ABCA4 | c.2168G>T p.R723I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV64671207; called by muse, mutect2, varscan2
- ABCA4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs62645942, CM043238; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2, varscan2
- ABCA5 | c.3892G>T p.E1298* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV67015797; called by muse, mutect2, varscan2
- ABCA5 | c.661A>C p.I221L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.562); catalogued as COSV101201021; called by muse, mutect2
- ABCA6 | c.4690G>T p.E1564* | Nonsense Mutation (SNP) | VAF 56/146 reads (38%) | catalogued as COSV52635928; called by muse, mutect2, varscan2
- ABCA6 | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52635943; called by muse, mutect2, varscan2
- ABCA8 | c.4654C>A p.L1552M | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV52194890; called by muse, mutect2, varscan2
- ABCA9 | c.434G>T p.R145I | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV60620849; called by muse, mutect2, varscan2
- ABCB1 | c.1480A>C p.N494H | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV55945523, COSV99712535; called by muse, mutect2, varscan2
- ABCB1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 40/118 reads (34%) | catalogued as rs1222604496, COSV55945529; called by muse, mutect2, varscan2
- ABCB1 | c.703-1G>T p.X235_splice | Splice Site (SNP) | VAF 24/86 reads (28%) | catalogued as COSV55945255, COSV55945538; called by muse, mutect2, varscan2
- ABCB1 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1288374568, COSV55945546; called by muse, mutect2, varscan2
- ABCB4 | c.2312T>G p.L771R | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55932240; called by muse, mutect2, varscan2
- ABCB4 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1437317341, COSV55932255; called by muse, mutect2, varscan2
- ABCB4 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs372685632, CM105787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.47G>T p.R16I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV68855019, COSV68856812; called by muse, mutect2, varscan2
- ABCB5 | c.1382G>A p.R461Q (on ENST00000404938 / NM_001163941.2; = p.R16Q on NM_178559.6) | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs201067658; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCB7 | c.961G>T p.E321* (on ENST00000373394 / NM_001271696.3; = p.E322* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 90/282 reads (32%) | catalogued as COSV53718077; called by muse, varscan2
- ABCB7 | c.491C>T p.A164V (on ENST00000373394 / NM_001271696.3; = p.A165V on NM_004299.6) | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.53); catalogued as COSV99503943; called by muse, mutect2
- ABCC1 | c.4378G>A p.V1460M | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs749468738, COSV60680737; called by muse, mutect2, varscan2
- ABCC11 | c.1720C>A p.L574M | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV62321429; called by muse, mutect2, varscan2
- ABCC11 | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62321440; called by muse, mutect2, varscan2
- ABCC11 | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV100750684, COSV62321442; called by muse, mutect2, varscan2
- ABCC12 | c.3464G>T p.R1155I | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60911762; called by muse, mutect2, varscan2
- ABCC12 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV60911768; called by muse, mutect2, varscan2
- ABCC2 | c.1099T>G p.L367V | Missense Mutation (SNP) | VAF 131/399 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV64970615; called by muse, mutect2, varscan2
- ABCC2 | c.1258A>G p.T420A | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100966413; called by muse, mutect2
- ABCC2 | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs777771609, COSV64984640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC2 | c.3399T>G p.I1133M | Missense Mutation (SNP) | VAF 150/415 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as CD061342, COSV64984650; called by muse, mutect2, varscan2
- ABCC4 | c.2992C>T p.R998* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | catalogued as rs149024948; called by muse, mutect2, varscan2
- ABCC4 | c.2905A>G p.I969V | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100972284; called by muse, mutect2
- ABCC5 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 98/337 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55587321; called by muse, mutect2, varscan2
- ABCC5 | c.2782C>A p.L928M | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as COSV55587332; called by muse, mutect2, varscan2
- ABCC5 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 95/305 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs563074461, COSV55587344; called by muse, mutect2, varscan2
- ABCD4 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778062723, COSV53990914; called by muse, mutect2, varscan2
- ABCE1 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs550948053, COSV56846273; called by muse, mutect2, varscan2
- ABCE1 | c.1788C>A p.F596L | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV56846283; called by muse, mutect2, varscan2
- ABCG2 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs142634180, COSV99419898; called by muse, mutect2, varscan2
- ABHD13 | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.25); catalogued as COSV65534390; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1357A>G p.N453D | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68343696; called by muse, mutect2, varscan2
- ABHD14B | c.454-1G>A p.X152_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV59985501; called by muse, mutect2, varscan2
- ABHD17A | c.694G>A p.D232N (on ENST00000292577 / NM_001130111.2; = p.D283N on NM_031213.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51749273; called by muse, mutect2, varscan2
- ABHD17C | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241550757, COSV51916573; called by muse, mutect2, varscan2
- ABHD3 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV56675686; called by muse, mutect2, varscan2
- ABHD5 | c.780C>A p.F260L (on ENST00000458276 / NM_001365650.1; = p.L323I on NM_016006.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/208 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV68904623; called by muse, mutect2, varscan2
- ABL2 | c.3532G>T p.D1178Y (on ENST00000502732 / NM_007314.4; = p.D1163Y on NM_005158.5) | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV61011228; called by muse, mutect2, varscan2
- ABL2 | c.158-1G>T p.X53_splice (on ENST00000502732 / NM_007314.4; = p.X38_splice on NM_005158.5) | Splice Site (SNP) | VAF 63/171 reads (37%) | catalogued as COSV61011240; called by muse, mutect2, varscan2
- ABLIM3 | c.1962C>A p.F654L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58639562, COSV58640456; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1226T>G p.F409C | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV55029242; called by muse, mutect2, varscan2
- ABRAXAS2 | c.291C>A p.F97L | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV100044854; called by muse, mutect2
- AC004593.2 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs753390011, COSV56087648; called by muse, mutect2, varscan2
- AC093827.5 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 62/163 reads (38%) | catalogued as COSV55744640, COSV99892827; called by muse, mutect2, varscan2
- ACAA1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151138541; called by muse, mutect2, varscan2
- ACACA | c.3050G>A p.R1017Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1385648978; called by muse, mutect2, varscan2
- ACACA | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs145246486; called by muse, mutect2, varscan2
- ACACB | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58128517; called by muse, mutect2, varscan2
- ACACB | c.1337G>T p.R446I | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV58128531; called by muse, mutect2, varscan2
- ACACB | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs755846803, COSV58128539; called by muse, mutect2, varscan2
- ACACB | c.5810G>T p.G1937V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58128546; called by muse, mutect2, varscan2
- ACADL | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 56/164 reads (34%) | catalogued as COSV52052210; called by muse, mutect2, varscan2
- ACADM | c.1037C>A p.S346Y | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV63719822, COSV63720479; called by muse, mutect2, varscan2
- ACAP2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 87/157 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV58749437; called by muse, mutect2, varscan2
- ACAP2 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV58749444, COSV58752279; called by muse, mutect2, varscan2
- ACAT2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV65453372; called by muse, mutect2, varscan2
- ACCS | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55457212; called by muse, mutect2, varscan2
- ACE2 | c.2365G>T p.G789* | Nonsense Mutation (SNP) | VAF 128/341 reads (38%) | catalogued as COSV53023821; called by muse, mutect2, varscan2
- ACE2 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.451); catalogued as COSV53023833, COSV53024244; called by muse, mutect2, varscan2
- ACE2 | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53023844; called by muse, mutect2, varscan2
- ACIN1 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV52972936, COSV52973539; called by muse, mutect2, varscan2
- ACLY | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as rs918567524, COSV61249335; called by muse, mutect2, varscan2
- ACO1 | c.1147T>G p.S383A | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV59377051, COSV59382821; called by muse, mutect2, varscan2
- ACOT12 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs576654714, COSV56892736; called by muse, mutect2, varscan2
- ACOT12 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 82/257 reads (32%) | catalogued as rs780095623, COSV56892749; called by muse, mutect2, varscan2
- ACOT13 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57763491; called by muse, mutect2, varscan2
- ACOT7 | c.331G>A p.D111N (on ENST00000377855 / NM_181864.3; = p.D101N on NM_007274.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); catalogued as rs758724954, COSV64111901; called by mutect2, varscan2
- ACOT9 | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV60536923; called by muse, mutect2, varscan2
- ACOT9 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV60536931; called by muse, mutect2, varscan2
- ACOX1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs780812320, COSV53131399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACOXL | c.249G>A p.E83= | Splice Region (SNP) | VAF 34/86 reads (40%) | catalogued as COSV61322087; called by muse, mutect2, varscan2
- ACP1 | c.390T>G p.D130E | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55242395; called by muse, varscan2
- ACP5 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.519); catalogued as rs1325584323, COSV54535306; called by muse, mutect2, varscan2
- ACP6 | c.1194C>A p.F398L | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV65076230; called by muse, mutect2, varscan2
- ACR | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as COSV53360380; called by muse, varscan2
- ACR | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs777620745, COSV53360385; called by muse, varscan2
- ACSBG2 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99397238; called by muse, varscan2
- ACSBG2 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV53123034; called by muse, mutect2, varscan2
- ACSBG2 | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV53123044; called by muse, mutect2, varscan2
- ACSL3 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62480859; called by muse, mutect2, varscan2
- ACSL4 | c.1820G>T p.S607I (on ENST00000340800 / NM_022977.2; = p.S566I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61613356; called by muse, mutect2, varscan2
- ACSL4 | c.1139G>T p.R380I (on ENST00000340800 / NM_022977.2; = p.R339I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100538330; called by muse, mutect2, varscan2
- ACSL4 | c.701A>C p.N234T (on ENST00000340800 / NM_022977.2; = p.N193T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV61613364; called by muse, mutect2, varscan2
- ACSL4 | c.338A>G p.K113R (on ENST00000340800 / NM_022977.2; = p.K72R on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.217); catalogued as COSV61613370; called by muse, mutect2, varscan2
- ACSM2A | c.991C>A p.L331I (on ENST00000219054; = p.L252I on NM_001308169.2) | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54582392; called by muse, varscan2
- ACSM2B | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV61656870, COSV61658390; called by muse, mutect2, varscan2
- ACSM3 | c.1045T>G p.C349G | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55500007; called by muse, mutect2, varscan2
- ACSM4 | c.151A>C p.N51H | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV68066761; called by muse, mutect2, varscan2
- ACSM4 | c.1643A>C p.K548T | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68066768; called by muse, mutect2, varscan2
- ACSS1 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.282); catalogued as COSV60217703; called by muse, mutect2, varscan2
- ACTL7A | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs770746389, COSV100453047; called by muse, mutect2, varscan2
- ACTL9 | c.403C>A p.H135N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV61004811; called by muse, mutect2, varscan2
- ACTR5 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs768522307, COSV54759775; called by muse, mutect2, varscan2
- ACTRT1 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64418954, COSV64420046; called by muse, mutect2, varscan2
- ACVR1C | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54643929; called by muse, mutect2, varscan2
- ACVR1C | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV99694397; called by muse, mutect2
- ACY3 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs755211338, COSV54828157; called by muse, mutect2, varscan2
- ACYP1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV53134529; called by muse, mutect2, varscan2
- ADAD1 | c.833G>T p.R278I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56641700, COSV99635256, COSV99636304; called by muse, mutect2, varscan2
- ADAD2 | c.479C>T p.T160I (on ENST00000315906 / NM_001145400.2; = p.T232I on NM_139174.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV51892463; called by muse, mutect2, varscan2
- ADAM10 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV53049411; called by muse, mutect2, varscan2
- ADAM17 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 134/285 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs780557617, COSV60397586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM17 | c.620-1G>A p.X207_splice | Splice Site (SNP) | VAF 103/222 reads (46%) | catalogued as COSV60397376, COSV60397591; called by muse, mutect2, varscan2
- ADAM18 | c.2183C>A p.S728* | Nonsense Mutation (SNP) | VAF 43/209 reads (21%) | catalogued as COSV55844091; called by muse, mutect2, varscan2
- ADAM19 | c.1558A>G p.T520A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57423281; called by muse, mutect2, varscan2
- ADAM2 | c.1867G>T p.D623Y | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55859057, COSV55868283; called by muse, mutect2, varscan2
- ADAM22 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.096); catalogued as COSV55970150; called by muse, mutect2, varscan2
- ADAM23 | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV52208159; called by muse, mutect2, varscan2
- ADAM23 | c.1237G>T p.G413* | Nonsense Mutation (SNP) | VAF 89/275 reads (32%) | catalogued as COSV52208183; called by muse, mutect2, varscan2
- ADAM30 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 197/574 reads (34%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.009); catalogued as rs1046963776, COSV65560431; called by muse, mutect2, varscan2
- ADAM32 | c.1161A>C p.K387N | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV65947291; called by muse, varscan2
- ADAM32 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.38); catalogued as rs766436330, COSV65947294; called by muse, mutect2, varscan2
- ADAM9 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 109/223 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV65958841; called by muse, mutect2, varscan2
- ADAM9 | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 21/393 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV101166026; called by muse, mutect2
- ADAM9 | c.1303-1G>T p.X435_splice | Splice Site (SNP) | VAF 17/166 reads (10%) | catalogued as COSV101166027; called by muse, mutect2
- ADAMDEC1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs753899251, COSV56474101; called by muse, mutect2, varscan2
- ADAMTS1 | c.1320C>A p.S440R | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV53168796; called by muse, mutect2, varscan2
- ADAMTS10 | c.2445C>A p.F815L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV54352196; called by muse, mutect2, varscan2
- ADAMTS10 | c.1383C>A p.D461E | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV54352210; called by muse, mutect2, varscan2
- ADAMTS12 | c.4537C>A p.L1513I | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV61256093; called by muse, mutect2, varscan2
- ADAMTS12 | c.874C>A p.H292N | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.359); catalogued as COSV61256100; called by muse, varscan2
- ADAMTS15 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372024440, COSV54503139; called by muse, mutect2, varscan2
- ADAMTS15 | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV54503157; called by muse, mutect2, varscan2
- ADAMTS15 | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1221223129, COSV54503176; called by muse, mutect2, varscan2
- ADAMTS16 | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56978991; called by muse, mutect2, varscan2
- ADAMTS17 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs139385294; called by muse, mutect2, varscan2
- ADAMTS17 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV51473773; called by muse, mutect2, varscan2
- ADAMTS18 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747748120, COSV51399155; called by muse, mutect2, varscan2
- ADAMTS19 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.185); catalogued as COSV50739347; called by muse, mutect2, varscan2
- ADAMTS19 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as COSV50732812, COSV50734177; called by muse, mutect2, varscan2
- ADAMTS2 | c.3217A>G p.M1073V | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV52365307; called by muse, mutect2, varscan2
- ADAMTS20 | c.4809C>A p.N1603K | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV67126626; called by muse, mutect2, varscan2
- ADAMTS5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286298815, COSV53175922; called by muse, mutect2, varscan2
- ADAMTS9 | c.4825T>G p.L1609V | Missense Mutation (SNP) | VAF 87/151 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV55775397; called by muse, mutect2, varscan2
- ADAMTS9 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 16/398 reads (4%) | catalogued as COSV55778753; called by muse, mutect2
- ADAMTSL1 | c.4594C>T p.R1532C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs778869300, COSV65876775, COSV65876864; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4213C>A p.L1405I | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54437172, COSV54450167; called by muse, mutect2, varscan2
- ADCY1 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52030467; called by muse, mutect2, varscan2
- ADCY10 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.115); catalogued as COSV63238660; called by muse, mutect2, varscan2
- ADCY10 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV63238666; called by muse, varscan2
- ADCY10 | c.287T>G p.F96C | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63238676; called by muse, varscan2
- ADCY2 | c.2311G>A p.V771M | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV57859884; called by muse, mutect2, varscan2
- ADCY3 | c.2577+1G>A p.X859_splice | Splice Site (SNP) | VAF 33/84 reads (39%) | catalogued as rs771918866, COSV53164640; called by muse, mutect2, varscan2
- ADCY5 | c.3650G>A p.R1217H | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.168); catalogued as rs770637165, COSV59194442, COSV59203728; called by muse, mutect2, varscan2
- ADCY6 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 172/476 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57166363; called by muse, mutect2, varscan2
- ADCY8 | c.3581C>T p.A1194V | Missense Mutation (SNP) | VAF 181/356 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as rs773491638, COSV53897305, COSV53908386; called by muse, mutect2, varscan2
- ADCY9 | c.2897C>T p.S966L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs777717895, COSV53571782, COSV53573711; called by mutect2, varscan2
- ADCY9 | c.2797C>T p.L933F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53571793; called by muse, mutect2, varscan2
- ADCY9 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV53571802; called by muse, mutect2, varscan2
- ADGRB3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs759189744, COSV65383753; called by muse, mutect2, varscan2
- ADGRB3 | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs895562853, COSV65383759; called by muse, mutect2, varscan2
- ADGRB3 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV65383764; called by muse, mutect2, varscan2
- ADGRB3 | c.1833C>A p.F611L | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.437); catalogued as COSV65383768; called by muse, mutect2, varscan2
- ADGRB3 | c.3364G>T p.D1122Y | Missense Mutation (SNP) | VAF 146/383 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53235293, COSV53262257; called by muse, mutect2, varscan2
- ADGRB3 | c.4454T>C p.I1485T | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV53235308; called by muse, mutect2, varscan2
- ADGRE3 | c.1815C>T p.V605= | Splice Region (SNP) | VAF 24/246 reads (10%) | catalogued as COSV99505892; called by muse, mutect2
- ADGRE5 | c.1858C>A p.H620N (on ENST00000242786 / NM_078481.4; = p.H527N on NM_001784.5) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54390468; called by muse, mutect2, varscan2
- ADGRF1 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as rs749943749, COSV51944055; called by muse, mutect2, varscan2
- ADGRF3 | c.963G>A p.W321* (on ENST00000311519 / NM_001145168.1; = p.W122* on NM_153835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV61048855; called by muse, mutect2, varscan2
- ADGRF4 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs772794418, COSV51949756; called by muse, mutect2, varscan2
- ADGRF5 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs199576297, COSV51930052; called by muse, mutect2, varscan2
- ADGRF5 | c.672-2A>G p.X224_splice | Splice Site (SNP) | VAF 120/345 reads (35%) | catalogued as COSV51930062; called by muse, mutect2, varscan2
- ADGRF5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757471686, COSV51930071; called by muse, mutect2, varscan2
- ADGRG2 | c.2650G>T p.E884* (on ENST00000379869 / NM_001079858.3; = p.E881* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 64/174 reads (37%) | catalogued as COSV61337653; called by muse, mutect2, varscan2
- ADGRG2 | c.1682C>T p.P561L (on ENST00000379869 / NM_001079858.3; = p.P558L on NM_005756.4) | Missense Mutation (SNP) | VAF 105/303 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs760652148, COSV61337657; called by muse, varscan2
- ADGRG3 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs771524034, COSV59650214; called by muse, mutect2, varscan2
- ADGRG4 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.249); catalogued as COSV54950069; called by muse, mutect2, varscan2
- ADGRG4 | c.2881A>C p.I961L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54950076; called by muse, mutect2, varscan2
- ADGRG4 | c.3918A>C p.K1306N | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV54950085; called by muse, varscan2
- ADGRG4 | c.5146G>A p.G1716S | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54950095; called by muse, mutect2, varscan2
- ADGRG4 | c.5827T>C p.S1943P | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54950105; called by muse, mutect2, varscan2
- ADGRG6 | c.1907C>A p.S636Y | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51587058; called by muse, varscan2
- ADGRG7 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56293928; called by muse, varscan2
- ADGRL2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1484112964, COSV54649480; called by muse, mutect2, varscan2
- ADGRL2 | c.2636G>A p.R879Q (on ENST00000370717 / NM_001366005.1; = p.R866Q on NM_012302.4) | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373312947; called by muse, mutect2, varscan2
- ADGRL3 | c.2134A>G p.N712D (on ENST00000506720 / NM_001322402.2; = p.N644D on NM_015236.6) | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV72229479; called by muse, mutect2, varscan2
- ADGRV1 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV67978978; called by muse, mutect2, varscan2
- ADGRV1 | c.4394G>T p.R1465I | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.967); catalogued as COSV67978984; called by muse, mutect2, varscan2
- ADGRV1 | c.7771G>A p.E2591K | Missense Mutation (SNP) | VAF 85/340 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs757315634, COSV67978987; called by muse, mutect2, varscan2
- ADGRV1 | c.9094C>T p.L3032F | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV67978992, COSV67980365; called by muse, mutect2, varscan2
- ADGRV1 | c.14404C>T p.R4802* | Nonsense Mutation (SNP) | VAF 51/133 reads (38%) | catalogued as rs1236715896, CM0911268, COSV67978996; called by muse, mutect2, varscan2
- ADGRV1 | c.14605C>T p.L4869F | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs371563402, COSV101315430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADH1A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1039874400, COSV52924296; called by muse, mutect2, varscan2
- ADH1B | c.1016A>C p.K339T | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV59295168; called by muse, mutect2, varscan2
- ADORA2A | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as COSV58377983; called by muse, mutect2, varscan2
- ADPRH | c.577A>T p.K193* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV63694457; called by muse, mutect2, varscan2
- ADPRH | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 92/178 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV63694464; called by muse, varscan2
- ADRA1B | c.858C>A p.F286L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100140110; called by muse, mutect2
- ADRA2B | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.544); catalogued as COSV69787216; called by muse, mutect2, varscan2
- ADSS2 | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100836807; called by muse, mutect2
- ADSS2 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV63694557, COSV63694846; called by muse, mutect2, varscan2
- ADTRP | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV99995084; called by muse, varscan2
- AEBP1 | c.1653G>T p.Q551H | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV56255598; called by muse, mutect2, varscan2
- AFAP1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs759888877, COSV61793397, COSV61797122; called by muse, mutect2, varscan2
- AFAP1L1 | c.698T>C p.F233S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57043913; called by muse, mutect2, varscan2
- AFDN | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60038131; called by muse, mutect2, varscan2
- AFDN | c.3116C>A p.S1039* | Nonsense Mutation (SNP) | VAF 90/363 reads (25%) | catalogued as COSV60038165, COSV60047101; called by muse, mutect2, varscan2
- AFF2 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60655390; called by muse, varscan2
- AFF2 | c.3620G>T p.G1207V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53977536, COSV53999460; called by muse, mutect2, varscan2
- AFF4 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV54791789; called by muse, mutect2, varscan2
- AFP | c.312T>G p.I104M | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV56924021; called by muse, mutect2, varscan2
- AFP | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV56924033; called by muse, mutect2, varscan2
- AFTPH | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV53215978; called by muse, mutect2, varscan2
- AGAP2 | c.1709G>A p.R570H (on ENST00000547588 / NM_001122772.2; = p.R234H on NM_014770.4) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs769607256, COSV57726906; called by muse, mutect2, varscan2
- AGAP2 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV57733856; called by muse, mutect2
- AGAP2 | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV57726919; called by muse, mutect2
- AGAP3 | c.758G>A p.R253Q (on ENST00000622464; = p.R289Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs754272615, COSV100103734; called by mutect2, varscan2
- AGAP3 | c.2308G>T p.A770S (on ENST00000622464; = p.A806S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68243307; called by muse, mutect2, varscan2
- AGAP6 | c.416T>C p.M139T (on ENST00000374056 / NM_001365867.1; = p.M162T on NM_001077665.2) | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV65017331; called by muse, varscan2
- AGBL1 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV69793231; called by muse, mutect2, varscan2
- AGBL1 | c.3031A>G p.R1011G | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV66849489; called by muse, mutect2, varscan2
- AGBL1 | c.3134A>G p.K1045R | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.16); catalogued as COSV101222325; called by muse, mutect2, varscan2
- AGBL4 | c.1159C>A p.L387I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.705); catalogued as COSV61890807; called by muse, mutect2, varscan2
- AGFG1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59510274; called by muse, mutect2, varscan2
- AGL | c.846+2T>C p.X282_splice | Splice Site (SNP) | VAF 36/107 reads (34%) | catalogued as COSV54048447; called by muse, mutect2, varscan2
- AGMO | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV61106121; called by muse, mutect2, varscan2
- AGMO | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61106127; called by muse, mutect2, varscan2
- AGPAT4 | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as COSV57243148; called by muse, mutect2, varscan2
- AGPS | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs1372190083, COSV51561302; called by muse, mutect2, varscan2
- AGPS | c.1948A>G p.N650D | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51561312; called by muse, mutect2, varscan2
- AGTPBP1 | c.2728C>T p.R910C (on ENST00000357081 / NM_001330701.2; = p.R870C on NM_015239.2) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61268816; called by muse, mutect2, varscan2
- AGTR2 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64156183; called by muse, varscan2
- AGTR2 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.106); catalogued as COSV64156187; called by muse, varscan2
- AGXT2 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 52/180 reads (29%) | catalogued as COSV51484087, COSV51490592, COSV99183908; called by muse, mutect2, varscan2
- AHCTF1 | c.1349C>T p.S450L (on ENST00000366508; = p.S424L on NM_015446.5) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs528013816, COSV58246078; called by muse, mutect2, varscan2
- AHCTF1 | c.363C>A p.F121L (on ENST00000366508; = p.F95L on NM_015446.5) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV58246083; called by muse, mutect2, varscan2
- AHCYL1 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 36/147 reads (24%) | catalogued as COSV63208225; called by muse, mutect2, varscan2
- AHCYL2 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61485236, COSV61491235; called by mutect2, varscan2
- AHNAK | c.8422G>A p.D2808N | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs1399506886, COSV99945917; called by muse, mutect2
- AHNAK | c.3697G>T p.G1233* | Nonsense Mutation (SNP) | VAF 150/397 reads (38%) | catalogued as COSV57204358; called by muse, mutect2, varscan2
- AHNAK2 | c.9721C>T p.R3241C | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs756188817, COSV60908478; called by muse, varscan2
- AHNAK2 | c.9466T>C p.S3156P | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60908481; called by muse, varscan2
- AHNAK2 | c.4846G>A p.D1616N | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs773853819, COSV100315997; called by muse, mutect2
- AHNAK2 | c.2488G>T p.D830Y | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60908483, COSV60908616; called by muse, varscan2
- AHNAK2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1311575783, COSV60908486; called by muse, mutect2, varscan2
- AHR | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV54121744; called by muse, mutect2, varscan2
- AIFM2 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs148682063; called by muse, mutect2, varscan2
- AIFM2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs376397847; called by muse, mutect2, varscan2
- AIG1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs201448093, COSV51622255, COSV99264016; called by muse, mutect2, varscan2
- AIRE | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778067704, COSV52392624; called by muse, mutect2, varscan2
- AJUBA | c.1510A>C p.S504R | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV52984512; called by muse, mutect2, varscan2
- AK2 | c.105A>C p.E35D (on ENST00000354858; = p.E77D on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV61466381; called by muse, mutect2, varscan2
- AK7 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs149622950, COSV50869271, COSV50871563; called by muse, mutect2, varscan2
- AK8 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs771154027, COSV53750859; called by muse, mutect2, varscan2
- AK9 | c.5664C>A p.F1888L | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as COSV69849197; called by muse, varscan2
- AK9 | c.3040A>C p.K1014Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV58137608; called by muse, mutect2, varscan2
- AK9 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 73/208 reads (35%) | catalogued as COSV58137635, COSV58149603; called by muse, mutect2, varscan2
- AKAP1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757287031, COSV58468807, COSV58471273; called by muse, mutect2, varscan2
- AKAP1 | c.1997A>G p.K666R | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV58468810; called by muse, varscan2
- AKAP1 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.047); catalogued as COSV58468817; called by muse, varscan2
- AKAP11 | c.4154A>C p.K1385T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV50292856; called by muse, mutect2, varscan2
- AKAP12 | c.3032A>G p.D1011G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV53570491; called by muse, mutect2, varscan2
- AKAP13 | c.7078G>T p.E2360* (on ENST00000394518 / NM_007200.5; = p.E2364* on NM_006738.6) | Nonsense Mutation (SNP) | VAF 52/135 reads (39%) | catalogued as COSV63449062; called by muse, mutect2, varscan2
- AKAP17A | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58308573; called by muse, mutect2, varscan2
- AKAP17A | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.603); catalogued as rs750245187, COSV58308585; called by muse, mutect2, varscan2
- AKAP3 | c.631A>C p.N211H | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV57414166; called by muse, mutect2, varscan2
- AKAP4 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62073755; called by muse, varscan2
- AKAP6 | c.1102A>G p.T368A | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV55205731; called by muse, mutect2, varscan2
- AKAP6 | c.2539C>A p.L847I | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55205743; called by muse, mutect2, varscan2
- AKAP6 | c.3351G>T p.E1117D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV55205754; called by muse, mutect2, varscan2
- AKAP6 | c.6203C>T p.S2068L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772533351, COSV55205772; called by muse, mutect2, varscan2
- AKAP7 | c.286A>C p.K96Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100818763; called by muse, mutect2
- AKAP7 | c.305T>G p.I102S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63504746; called by muse, mutect2, varscan2
- AKAP7 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 55/158 reads (35%) | catalogued as COSV53833574; called by muse, mutect2, varscan2
- AKAP9 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV62339276; called by muse, mutect2, varscan2
- AKAP9 | c.3164C>A p.S1055Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs373730126; called by muse, mutect2, varscan2
- AKAP9 | c.8464C>A p.L2822I (on ENST00000359028; = p.L2798I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV62339320, COSV62351713; called by muse, mutect2, varscan2
- AKIRIN2 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 106/303 reads (35%) | catalogued as COSV57636007; called by muse, mutect2, varscan2
- AKNAD1 | c.1451A>C p.K484T | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV62195100; called by muse, mutect2, varscan2
- AKR1C1 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs782766545, COSV66498663; called by muse, mutect2, varscan2
- AKR1C2 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 161/475 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV66332607; called by muse, mutect2, varscan2
- AKR1C8P | c.248T>G p.F83C | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554792889; called by muse, mutect2, varscan2
- AKR1E2 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 56/204 reads (27%) | catalogued as COSV53629656; called by muse, varscan2
- AL121899.2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs772149238, COSV101198558, COSV67349773; called by muse, mutect2, varscan2
- AL645922.1 | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100190723; called by muse, mutect2, varscan2
- ALAS2 | c.1241C>A p.A414D | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58188502; called by muse, mutect2, varscan2
- ALB | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs141343001, COSV55735894; called by muse, mutect2, varscan2
- ALDH1A3 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as rs772610695, COSV60900907, COSV60903325; called by muse, mutect2, varscan2
- ALDH9A1 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs775405930, COSV61339076; called by muse, mutect2, varscan2
- ALG10B | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as COSV58142382; called by muse, mutect2, varscan2
- ALG13 | c.1187G>T p.R396I | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52635440; called by muse, mutect2, varscan2
- ALG9 | c.1666G>T p.E556* (on ENST00000614444 / NM_001352418.1; = p.E563* on NM_024740.2) | Nonsense Mutation (SNP) | VAF 72/217 reads (33%) | catalogued as COSV67643615; called by muse, mutect2, varscan2
- ALG9 | c.1420C>T p.R474* (on ENST00000614444 / NM_001352418.1; = p.R481* on NM_024740.2) | Nonsense Mutation (SNP) | VAF 67/169 reads (40%) | catalogued as COSV67643616, COSV67643793; called by muse, mutect2, varscan2
- ALK | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV66558174, COSV66563195; called by muse, varscan2
- ALKAL1 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62129891; called by muse, mutect2, varscan2
- ALKBH6 | c.118C>T p.R40* (on ENST00000252984 / NM_001297701.2; = p.R68* on NM_032878.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/148 reads (32%) | catalogued as rs1247337824, COSV53323984; called by muse, mutect2, varscan2
- ALMS1 | c.4471C>T p.P1491S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV52503353; called by muse, mutect2, varscan2
- ALOX12B | c.1427A>C p.Y476S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59871174; called by muse, mutect2, varscan2
- ALOXE3 | c.1869G>T p.K623N | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV59074086; called by muse, mutect2, varscan2
- ALPK1 | c.2240T>G p.I747S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.163); catalogued as COSV51582091; called by muse, mutect2, varscan2
- ALPK1 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200148939; called by muse, mutect2, varscan2
- ALPK3 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs777370400, COSV51930090; called by muse, mutect2, varscan2
- ALS2 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1054031459, CM1310480, COSV51884292; called by muse, mutect2, varscan2
- ALX1 | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57491240; called by muse, mutect2, varscan2
- ALX4 | c.624G>T p.E208D | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV61324878; called by muse, mutect2, varscan2
- AMACR | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs774406448, COSV56869837; called by muse, varscan2
- AMACR | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 65/172 reads (38%) | catalogued as COSV56869842, COSV99672137; called by muse, varscan2
- AMBP | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 98/328 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV54322370; called by muse, mutect2, varscan2
- AMELX | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); catalogued as COSV61624313; called by muse, mutect2, varscan2
- AMER2 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as rs1429856634, COSV63436291; called by muse, mutect2, varscan2
- AMMECR1 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 69/341 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53316227; called by muse, mutect2, varscan2
- AMMECR1L | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1411675264, COSV55760064; called by muse, mutect2
- AMOT | c.2111C>A p.A704D (on ENST00000371959 / NM_001113490.1; = p.A295D on NM_133265.3) | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV59060781; called by muse, mutect2, varscan2
- AMPD1 | c.1147A>T p.M383L | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62415068; called by muse, mutect2, varscan2
- AMY1C | c.1025T>C p.F342S | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100915187; called by muse, mutect2
- ANAPC1 | c.5308C>A p.L1770I | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as COSV61974308, COSV61978513; called by muse, mutect2, varscan2
- ANAPC5 | c.1515+2T>A p.X505_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as COSV55841486; called by muse, mutect2, varscan2
- ANAPC5 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55841494; called by muse, mutect2, varscan2
- ANGPTL1 | c.740G>T p.R247I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as COSV52365435; called by muse, mutect2, varscan2
- ANGPTL5 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.72); catalogued as rs1046956838, COSV57531925, COSV57533782; called by muse, mutect2, varscan2
- ANGPTL5 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57531935; called by muse, mutect2, varscan2
- ANK2 | c.3958G>T p.E1320* | Nonsense Mutation (SNP) | VAF 50/140 reads (36%) | catalogued as COSV52147265, COSV52147733; called by muse, mutect2, varscan2
- ANK2 | c.5350C>T p.R1784* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV52147279; called by muse, mutect2, varscan2
- ANK2 | c.7564C>A p.L2522I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV52147287; called by muse, mutect2, varscan2
- ANK2 | c.7964C>T p.S2655L | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs373153154, COSV52147308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.7100G>A p.R2367Q | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs775210756, COSV55045223; called by muse, varscan2
- ANK3 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 107/249 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55045239; called by muse, mutect2, varscan2
- ANKAR | c.590T>G p.F197C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55609728; called by mutect2, varscan2
- ANKAR | c.3620A>C p.H1207P | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs571210494, COSV55609746; called by muse, mutect2, varscan2
- ANKDD1A | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV63086844; called by muse, mutect2, varscan2
- ANKEF1 | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as rs767339625, COSV65691980; called by muse, mutect2, varscan2
- ANKFN1 | c.1567-1G>T p.X523_splice | Splice Site (SNP) | VAF 43/148 reads (29%) | catalogued as COSV59441401; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.031); catalogued as COSV51840824, COSV51840883; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4100G>A p.R1367H | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757899078, COSV51840263; called by muse, mutect2, varscan2
- ANKLE1 | c.1409C>T p.T470M (on ENST00000394458; = p.T416M on NM_152363.6) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760470646, COSV63919953; called by muse, mutect2, varscan2
- ANKLE2 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs751601869, COSV61707901; called by muse, mutect2, varscan2
- ANKMY1 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs777607206, COSV56030414; called by muse, mutect2, varscan2
- ANKMY1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1472021219, COSV56030432; called by muse, mutect2, varscan2
- ANKRD1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs775584071, COSV65467204, COSV65467871; called by muse, mutect2, varscan2
- ANKRD1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs1293523344, COSV65467209; called by muse, varscan2
- ANKRD11 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs1183047246, COSV56355432; called by muse, mutect2, varscan2
- ANKRD12 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 23/156 reads (15%) | catalogued as COSV50819411, COSV50821436; called by muse, mutect2, varscan2
- ANKRD12 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 47/102 reads (46%) | catalogued as rs766734820, COSV50819104; called by muse, mutect2, varscan2
- ANKRD12 | c.4162C>A p.L1388I | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV50819429, COSV50823705; called by muse, mutect2, varscan2
- ANKRD12 | c.5456C>A p.S1819Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV50819436; called by muse, mutect2, varscan2
- ANKRD13A | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763901109, COSV55675252, COSV55679096; called by muse, varscan2
- ANKRD13B | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163651961, COSV67473436; called by mutect2, varscan2
- ANKRD24 | c.3178G>T p.E1060* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53667893; called by muse, mutect2, varscan2
- ANKRD26 | c.4861C>T p.L1621F | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65774130; called by muse, mutect2, varscan2
- ANKRD26 | c.3439C>T p.R1147* | Nonsense Mutation (SNP) | VAF 103/274 reads (38%) | catalogued as rs151033255, COSV65774138; called by muse, mutect2, varscan2
- ANKRD27 | c.2663A>T p.K888I | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV60129059; called by muse, mutect2, varscan2
- ANKRD27 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as rs754133011, COSV60129071; called by muse, mutect2, varscan2
- ANKRD30A | c.1146G>T p.K382N (on ENST00000611781; = p.K326N on NM_052997.2) | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV64603615; called by muse, varscan2
- ANKRD30A | c.1201G>T p.E401* (on ENST00000611781; = p.E345* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 42/84 reads (50%) | catalogued as COSV100653034, COSV64611018; called by muse, varscan2
- ANKRD30A | c.3229G>T p.D1077Y (on ENST00000611781; = p.D1021Y on NM_052997.2) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100654526, COSV64604435; called by muse, mutect2, varscan2
- ANKRD37 | c.467G>T p.R156M | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52990615; called by muse, mutect2, varscan2
- ANKRD42 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV52614463; called by muse, mutect2, varscan2
- ANKRD49 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57059788; called by muse, mutect2
- ANKRD55 | c.1730C>A p.S577Y | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV61944473; called by muse, mutect2, varscan2
- ANKS3 | c.1246A>G p.S416G | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV58507328; called by muse, mutect2, varscan2
- ANKS4B | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs531162767, COSV61138806; called by muse, mutect2, varscan2
- ANLN | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs923512260, COSV56074093; called by muse, mutect2, varscan2
- ANO10 | c.1635C>A p.F545L | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV52728646; called by muse, mutect2, varscan2
- ANO2 | c.1984G>T p.E662* (on ENST00000356134 / NM_001278597.3; = p.E666* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 49/153 reads (32%) | catalogued as COSV59008703, COSV59045108; called by muse, mutect2, varscan2
- ANO5 | c.2156C>G p.T719S | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV61082290; called by muse, mutect2, varscan2
- ANO6 | c.1713C>A p.F571L | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761477437, COSV57657199; called by muse, mutect2, varscan2
- ANO7 | c.1739A>C p.Q580P (on ENST00000274979; = p.Q526P on NM_001370694.2) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV51468535; called by muse, mutect2, varscan2
- ANTXR2 | c.373A>C p.K125Q | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV55017343; called by muse, mutect2, varscan2
- ANXA2 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV60315609; called by muse, mutect2, varscan2
- ANXA4 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.886); catalogued as COSV101268775; called by muse, mutect2
- ANXA5 | c.781G>T p.G261* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV56638298; called by mutect2, varscan2
- AOC2 | c.2118C>A p.F706L (on ENST00000253799 / NM_009590.4; = p.F679L on NM_001158.5) | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs772005140, COSV53824129, COSV53826096; called by muse, mutect2, varscan2
- AOPEP | c.319A>C p.K107Q | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV52914863; called by muse, mutect2, varscan2
- AOX1 | c.2381A>G p.N794S | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); catalogued as COSV65980199; called by muse, mutect2, varscan2
- AP002512.3 | c.1187G>T p.R396I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs958894838, COSV54405610; called by muse, mutect2, varscan2
- AP002512.3 | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV54405624; called by muse, mutect2, varscan2
- AP002512.3 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.39); catalogued as rs1326016320, COSV56565765; called by muse, mutect2, varscan2
- AP2A2 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 43/143 reads (30%) | catalogued as COSV59958193; called by muse, mutect2, varscan2
- AP2B1 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 42/118 reads (36%) | catalogued as COSV51997092; called by muse, mutect2, varscan2
- AP2B1 | c.1541C>A p.S514Y | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51997209; called by muse, mutect2, varscan2
- AP3B1 | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 26/209 reads (12%) | catalogued as rs773298750, CM1514510, COSV54876776; called by muse, mutect2, varscan2
- AP3B1 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV54876791; called by muse, mutect2, varscan2
- AP3B2 | c.2898C>A p.F966L (on ENST00000261722; = p.F960L on NM_004644.5) | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.667); catalogued as COSV99916120; called by muse, mutect2
- AP3B2 | c.1955C>A p.S652Y | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1164484702, COSV55606700; called by muse, mutect2, varscan2
- AP3M2 | c.650A>C p.D217A | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51527693; called by muse, mutect2, varscan2
- AP4B1 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs762612591, COSV56723465, COSV56726282; called by muse, mutect2, varscan2
- AP5M1 | c.1007G>T p.R336I | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV55104548; called by muse, mutect2, varscan2
- APAF1 | c.508G>T p.D170Y (on ENST00000551964 / NM_181861.2; = p.D159Y on NM_001160.3) | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54488543; called by muse, mutect2, varscan2
- APC | c.3230T>A p.V1077D | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV57326447; called by muse, mutect2, varscan2
- APC | c.3893C>A p.S1298Y | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV57326455; called by muse, mutect2, varscan2
- APC | c.7391C>A p.S2464Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766473931, COSV57326479, COSV57388076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLF | c.914C>A p.S305Y | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58142685; called by muse, mutect2, varscan2
- APOA4 | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.315); catalogued as COSV63360038; called by muse, mutect2, varscan2
- APOB | c.11104C>A p.L3702I | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV51922619; called by muse, mutect2, varscan2
- APOB | c.7511C>A p.S2504Y | Missense Mutation (SNP) | VAF 142/276 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51924144; called by muse, mutect2, varscan2
- APOB | c.2771T>G p.F924C | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51924160; called by muse, mutect2, varscan2
- APOB | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs145661815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC1 | c.467T>C p.F156S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1039779409, COSV57548250; called by muse, mutect2, varscan2
- APOBEC1 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57548258; called by muse, mutect2, varscan2
- APOBEC2 | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV55142035; called by muse, mutect2, varscan2
- APOBEC3D | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV53325681; called by muse, mutect2, varscan2
- APOBEC3F | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.371); catalogued as rs374582155; called by muse, mutect2, varscan2
- APOBEC3G | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1011553055, COSV68469998; called by muse, mutect2, varscan2
- APOBEC4 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as rs1263925383, COSV58016909; called by muse, mutect2, varscan2
- APOF | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 72/164 reads (44%) | catalogued as rs932985798, COSV58474359; called by muse, varscan2
- APOLD1 | c.609C>A p.F203L (on ENST00000326765 / NM_001130415.2; = p.F172L on NM_030817.3) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV58731825; called by muse, mutect2, varscan2
- APP | c.2292C>A p.F764L | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382239795, COSV60994133; called by muse, mutect2, varscan2
- APP | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 98/303 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60994141; called by muse, mutect2, varscan2
- APP | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as rs201573490, COSV60994151; called by muse, mutect2, varscan2
- APPL1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1213897253, COSV55699788; called by muse, mutect2, varscan2
- APTX | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs371292546, COSV58928296; ClinVar: uncertain significance; called by muse, varscan2
- APTX | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs772656348, COSV58927605; called by muse, varscan2
- AQR | c.3830G>A p.R1277Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50029799; called by muse, mutect2, varscan2
- AQR | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as rs769956783, COSV50029808; called by muse, mutect2, varscan2
- AQR | c.109A>G p.K37E | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV50029819; called by muse, varscan2
- ARAP1 | c.4050G>T p.K1350N (on ENST00000393609 / NM_001040118.2; = p.K1105N on NM_015242.4) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61989489; called by muse, mutect2, varscan2
- ARAP2 | c.5105T>G p.I1702S | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58282816; called by muse, mutect2, varscan2
- ARAP2 | c.4608+1G>A p.X1536_splice | Splice Site (SNP) | VAF 19/59 reads (32%) | catalogued as rs1413546631, COSV58282826; called by muse, mutect2, varscan2
- ARAP2 | c.2736G>T p.E912D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.306); catalogued as COSV58283236; called by muse, mutect2
- ARAP2 | c.2333A>G p.H778R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs747870799, COSV58282843; called by muse, mutect2, varscan2
- ARAP3 | c.2802G>T p.G934= | Splice Region (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99499391; called by muse, mutect2
- ARF5 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs773554378, COSV50000329; called by muse, mutect2, varscan2
- ARFGEF1 | c.5042A>C p.K1681T | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV51602882; called by muse, mutect2, varscan2
- ARFGEF1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51602906, COSV99141102; called by muse, mutect2, varscan2
- ARFGEF1 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602923; called by muse, mutect2, varscan2
- ARFGEF3 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs374061664; called by muse, mutect2, varscan2
- ARG2 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1566803283, COSV55777318; called by muse, mutect2
- ARGFX | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 93/483 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1238000316, COSV100544073; called by muse, mutect2, varscan2
- ARHGAP10 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | catalogued as COSV60595214; called by muse, mutect2, varscan2
- ARHGAP11A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 118/337 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254258669, COSV100853282, COSV64380589; called by muse, mutect2, varscan2
- ARHGAP11A | c.1224A>C p.K408N | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64380590; called by muse, mutect2, varscan2
- ARHGAP11A | c.1782G>T p.E594D | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV64380591; called by muse, mutect2, varscan2
- ARHGAP11B | c.297G>A p.K99= | Splice Region (SNP) | VAF 103/252 reads (41%) | catalogued as COSV70288293; called by muse, varscan2
- ARHGAP12 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 208/520 reads (40%) | catalogued as COSV60961498; called by muse, mutect2, varscan2
- ARHGAP19 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV57391470; called by muse, mutect2, varscan2
- ARHGAP20 | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99503255; called by muse, mutect2
- ARHGAP21 | c.4772C>T p.S1591L | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs767734882, COSV57602396; called by muse, mutect2, varscan2
- ARHGAP21 | c.3166C>T p.R1056* | Nonsense Mutation (SNP) | VAF 159/372 reads (43%) | catalogued as COSV57602405; called by muse, mutect2, varscan2
- ARHGAP25 | c.794C>T p.A265V (on ENST00000409202 / NM_001007231.3; = p.A257V on NM_014882.3) | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1481204393, COSV54898666; called by muse, mutect2, varscan2
- ARHGAP25 | c.1463C>A p.S488Y (on ENST00000409202 / NM_001007231.3; = p.S480Y on NM_014882.3) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54898685; called by muse, mutect2, varscan2
- ARHGAP29 | c.3433G>T p.D1145Y | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV53108633; called by muse, mutect2, varscan2
- ARHGAP31 | c.2056C>A p.L686I | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV51789406; called by muse, varscan2
- ARHGAP35 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV68329300; called by muse, mutect2, varscan2
- ARHGAP35 | c.2597C>A p.S866Y | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68329306, COSV68332376; called by muse, mutect2, varscan2
- ARHGAP35 | c.2835G>T p.K945N | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101350747; called by muse, mutect2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP36 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1220855026, COSV52263942, COSV99357184; called by muse, mutect2, varscan2
- ARHGAP4 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1569546003, COSV100604122, COSV63130805; called by muse, mutect2, varscan2
- ARHGAP45 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57429467; called by muse, mutect2, varscan2
- ARHGAP5 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV61534005; called by muse, mutect2, varscan2
- ARHGAP5 | c.4357G>T p.E1453* (on ENST00000345122 / NM_001030055.2; = p.E1452* on NM_001173.3) | Nonsense Mutation (SNP) | VAF 37/120 reads (31%) | catalogued as COSV53734979, COSV53735362; called by muse, mutect2, varscan2
- ARHGAP9 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62721385; called by muse, varscan2
- ARHGEF10 | c.329C>T p.P110L (on ENST00000398564; = p.P86L on NM_014629.4) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs778761628, COSV50642839; called by muse, mutect2, varscan2
- ARHGEF10 | c.1654G>A p.D552N (on ENST00000398564; = p.D527N on NM_014629.4) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368618077, COSV50642845; called by muse, mutect2, varscan2
- ARHGEF11 | c.3625C>T p.R1209* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as rs1036932379, COSV59352521; called by muse, mutect2, varscan2
- ARHGEF11 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as COSV59353278; called by muse, mutect2
- ARHGEF12 | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV63102772; called by muse, mutect2, varscan2
- ARHGEF12 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767889107, COSV63102781; called by muse, mutect2, varscan2
- ARHGEF12 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | catalogued as COSV63102787; called by muse, mutect2, varscan2
- ARHGEF12 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1228103500, COSV63102793; called by muse, varscan2
- ARHGEF15 | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV62724397; called by muse, mutect2, varscan2
- ARHGEF25 | c.590A>G p.E197G | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV54084603; called by muse, mutect2, varscan2
- ARHGEF25 | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV54084623; called by muse, mutect2, varscan2
- ARHGEF3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 256/342 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs866259310, COSV56323686; called by muse, mutect2, varscan2
- ARHGEF5 | c.3933T>G p.I1311M | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50207771; called by mutect2, varscan2
- ARHGEF7 | c.973T>G p.F325V (on ENST00000375741 / NM_001113511.2; = p.F147V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV54539148; called by muse, varscan2
- ARID1A | c.2974G>T p.E992* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV61372304; called by muse, mutect2, varscan2
- ARID1A | c.4856C>T p.P1619L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs763947592, COSV61372309, COSV61372492; called by muse, mutect2, varscan2
- ARID3C | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99426767; called by muse, mutect2
- ARID4A | c.3014T>C p.V1005A | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV62162073; called by muse, mutect2, varscan2
- ARID4A | c.3647G>T p.R1216I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777008968, COSV62162083; called by muse, mutect2, varscan2
- ARID4B | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1314403068, COSV51598595; called by muse, mutect2, varscan2
- ARID5B | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV54414685; called by muse, mutect2, varscan2
- ARID5B | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as COSV54414696, COSV54429284; called by muse, mutect2, varscan2
- ARID5B | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | catalogued as COSV54414394, COSV54414704, COSV54420304; called by muse, mutect2, varscan2
- ARID5B | c.3266C>T p.S1089L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs1170860237, COSV54414711; called by muse, mutect2, varscan2
- ARIH1 | c.754T>G p.S252A | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV65910480; called by muse, mutect2, varscan2
- ARL13A | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV65879962; called by muse, mutect2, varscan2
- ARL13A | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV65879964; called by muse, mutect2, varscan2
- ARL13A | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as COSV65879968; called by muse, mutect2, varscan2
- ARL13B | c.619G>T p.E207* (on ENST00000394222 / NM_001174150.2; = p.E100* on NM_144996.4) | Nonsense Mutation (SNP) | VAF 11/121 reads (9%) | catalogued as COSV100115215; called by muse, mutect2
- ARL14 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV57899577; called by muse, mutect2, varscan2
- ARL6 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV60117042; called by mutect2, varscan2
- ARL6IP4 | c.897G>T p.K299N (on ENST00000315580 / NM_018694.3; = p.K280N on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV99758413; called by mutect2, varscan2
- ARL6IP5 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs11542221, COSV56234277; called by muse, mutect2, varscan2
- ARL8B | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as COSV56577147; called by muse, mutect2, varscan2
- ARMC12 | c.466G>A p.E156K (on ENST00000373866 / NM_001286574.2; = p.E183K on NM_145028.5) | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs148096096; called by muse, mutect2, varscan2
- ARMC2 | c.2518G>T p.E840* | Nonsense Mutation (SNP) | VAF 44/142 reads (31%) | catalogued as COSV64550027; called by muse, mutect2, varscan2
- ARMC3 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53057334; called by muse, mutect2, varscan2
- ARMC3 | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV53057202, COSV53057353; called by muse, mutect2, varscan2
- ARMC8 | c.124G>T p.D42Y (on ENST00000469044 / NM_001363941.2; = p.D28Y on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV61767696; called by muse, varscan2
- ARMC8 | c.1771G>T p.D591Y (on ENST00000469044 / NM_001363941.2; = p.D577Y on NM_015396.6) | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV58616684; called by muse, mutect2, varscan2
- ARMCX1 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV65704902; called by muse, mutect2, varscan2
- ARMCX2 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as rs782562393, COSV57529302; called by muse, mutect2, varscan2
- ARMCX2 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.146); catalogued as COSV57529257; called by muse, mutect2, varscan2
- ARMCX3 | c.1019T>G p.F340C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV57869737; called by muse, mutect2, varscan2
- ARMCX5 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1298188206, COSV55765940; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63437139; called by muse, mutect2, varscan2
- ARMH4 | c.2263G>T p.E755* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as COSV50761784, COSV50768702; called by muse, mutect2, varscan2
- ARMH4 | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 228/657 reads (35%) | catalogued as COSV50761797; called by muse, mutect2, varscan2
- ARPP21 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 100/195 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV51792546; called by muse, mutect2, varscan2
- ARPP21 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 71/306 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV51792561; called by muse, mutect2, varscan2
- ARPP21 | c.1772G>A p.S591N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99491220; called by muse, mutect2
- ARR3 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV52103272; called by muse, varscan2
- ARRDC3 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as rs777796833, COSV54364590; called by muse, mutect2, varscan2
- ARRDC5 | c.721C>T p.R241W (on ENST00000381781; = p.R227W on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs368150405, COSV67787740; called by muse, mutect2, varscan2
- ARSF | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV63839028; called by muse, mutect2, varscan2
- ARSH | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV66962562; called by muse, mutect2, varscan2
- ARSH | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs759497002, COSV66962565; called by muse, mutect2, varscan2
- ARX | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421460479, COSV66874805; called by muse, mutect2, varscan2
- ASAP1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs201186844, COSV100726899; called by muse, mutect2, varscan2
- ASAP2 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55639213; called by muse, mutect2
- ASAP3 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.005); catalogued as COSV60873152; called by muse, mutect2, varscan2
- ASB1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as rs766647017, COSV52826360; called by muse, mutect2, varscan2
- ASB11 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV60354331; called by muse, mutect2, varscan2
- ASB12 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750364527, COSV62856092; called by muse, mutect2, varscan2
- ASB14 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 18/318 reads (6%) | catalogued as COSV99897449; called by muse, mutect2
- ASB14 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV67466940; called by muse, mutect2, varscan2
- ASB4 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57507376; called by muse, mutect2, varscan2
- ASB4 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs757471123, COSV57943093; called by muse, mutect2, varscan2
- ASB5 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV56668803; called by muse, mutect2, varscan2
- ASCC3 | c.2314C>T p.R772* | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as rs761797390, COSV61225918; called by muse, mutect2, varscan2
- ASH1L | c.7759C>T p.R2587C (on ENST00000368346 / NM_001366177.2; = p.R2582C on NM_018489.3) | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs760100125, COSV64205642; called by muse, mutect2, varscan2
- ASH1L | c.6721C>T p.R2241W (on ENST00000368346 / NM_001366177.2; = p.R2236W on NM_018489.3) | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64205647; called by muse, varscan2
- ASH1L | c.6713G>A p.G2238E (on ENST00000368346 / NM_001366177.2; = p.G2233E on NM_018489.3) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64205653; called by muse, varscan2
- ASH1L | c.3962G>A p.R1321Q | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs1358026443, COSV64205657; called by muse, mutect2, varscan2
- ASH1L | c.3191C>A p.S1064Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV64205662; called by muse, mutect2, varscan2
- ASIC3 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV52520609; called by muse, mutect2, varscan2
- ASIC4 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV61730987; called by mutect2, varscan2
- ASIC5 | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV73332583; called by muse, mutect2, varscan2
- ASIC5 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV73332585; called by muse, mutect2, varscan2
- ASIC5 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 46/116 reads (40%) | catalogued as COSV72232517, COSV72232612; called by muse, mutect2, varscan2
- ASNS | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV51550360; called by muse, varscan2
- ASNSD1 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 63/202 reads (31%) | catalogued as rs1472849676, COSV53622963; called by muse, mutect2, varscan2
- ASPM | c.7325G>A p.R2442Q | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745339338, COSV99659686; called by muse, varscan2
- ASPM | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756067585, COSV54125044; called by muse, mutect2, varscan2
- ASTN2 | c.3692C>T p.S1231L (on ENST00000313400 / NM_001365069.1; = p.S1180L on NM_014010.5) | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1458214989, COSV55999388; called by muse, varscan2
- ASXL2 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV55453991, COSV55459868; called by muse, mutect2, varscan2
- ASXL3 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99323704; called by muse, mutect2
- ASXL3 | c.2173A>G p.T725A | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV52457996; called by muse, mutect2, varscan2
- ASXL3 | c.3814A>G p.T1272A | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV52458013; called by muse, mutect2, varscan2
- ASXL3 | c.6119C>T p.P2040L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.257); catalogued as rs765788846, COSV52458026; called by muse, mutect2, varscan2
- ATAD1 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 57/163 reads (35%) | catalogued as rs1183753874, COSV57755834; called by muse, mutect2, varscan2
- ATAD2 | c.2459T>G p.F820C | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV54877519; called by muse, varscan2
- ATAD2 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1257928654, COSV54877532; called by muse, varscan2
- ATAD2 | c.2219C>A p.S740Y | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV54877540; called by muse, mutect2, varscan2
- ATAD2 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 53/98 reads (54%) | catalogued as COSV54877562, COSV99783859; called by muse, mutect2, varscan2
- ATAD2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs555718366, COSV54877572; called by muse, mutect2, varscan2
- ATAD2B | c.3352A>C p.N1118H | Missense Mutation (SNP) | VAF 126/358 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); catalogued as COSV53195423; called by muse, mutect2, varscan2
- ATAD2B | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 112/322 reads (35%) | catalogued as COSV53195436; called by muse, mutect2, varscan2
- ATAD2B | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as rs1029580293, COSV53201977; called by muse, mutect2
- ATAD3A | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 45/365 reads (12%) | catalogued as COSV59231863; called by muse, mutect2, varscan2
- ATAD3B | c.778G>A p.A260T (on ENST00000308647; = p.A366T on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs757157792, COSV100426312; called by muse, mutect2
- ATAD5 | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV58972195; called by muse, mutect2, varscan2
- ATCAY | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56654363; called by muse, mutect2, varscan2
- ATF1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV50394025; called by muse, mutect2, varscan2
- ATF2 | c.1076T>G p.L359* | Nonsense Mutation (SNP) | VAF 24/264 reads (9%) | catalogued as COSV99908439; called by muse, mutect2
- ATF6B | c.431T>G p.F144C | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as COSV64322307; called by muse, mutect2, varscan2
- ATF7IP | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV53766662; called by muse, mutect2, varscan2
- ATF7IP | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV53771644, COSV99661271; called by muse, mutect2, varscan2
- ATF7IP | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs775807378, COSV53766672; called by muse, mutect2, varscan2
- ATF7IP2 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 79/177 reads (45%) | catalogued as COSV61092262; called by muse, mutect2, varscan2
- ATG2B | c.6173G>T p.R2058I | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55889456; called by muse, mutect2, varscan2
- ATG4B | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs571586050, COSV60349391; called by muse, mutect2, varscan2
- ATG4C | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 39/96 reads (41%) | catalogued as COSV58603846; called by muse, mutect2, varscan2
- ATG4C | c.1217A>T p.K406I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV58603860; called by muse, mutect2, varscan2
- ATG7 | c.2017C>A p.H673N | Missense Mutation (SNP) | VAF 114/211 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.257); catalogued as COSV61611160; called by muse, mutect2, varscan2
- ATL2 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60050572; called by muse, mutect2, varscan2
- ATL2 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV60050585; called by muse, mutect2, varscan2
- ATM | c.1444A>C p.K482Q | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs202173660; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATM | c.4222C>A p.L1408I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53727629, COSV53733404; called by muse, mutect2, varscan2
- ATM | c.4315C>A p.L1439I | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV53727644; called by muse, mutect2, varscan2
- ATMIN | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs199541307, COSV55145212; called by muse, mutect2, varscan2
- ATOH1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60037460; called by muse, mutect2, varscan2
- ATP10A | c.3874T>G p.F1292V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100790962; called by muse, mutect2
- ATP10A | c.1173C>A p.F391L | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.534); catalogued as COSV63513826; called by muse, mutect2, varscan2
- ATP10B | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.433); catalogued as COSV59144231; called by muse, mutect2, varscan2
- ATP10B | c.1870C>T p.L624F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as rs201525382, COSV100514313; called by muse, mutect2
- ATP10D | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs750138858, COSV56704068; called by muse, mutect2, varscan2
- ATP10D | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561130132, COSV56703624; called by muse, mutect2, varscan2
- ATP11A | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs775471189, COSV52106463; called by mutect2, varscan2
- ATP11A | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1031257680, COSV52106477; called by muse, mutect2, varscan2
- ATP11B | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 97/206 reads (47%) | catalogued as rs1423341970, COSV60026312, COSV60030848; called by muse, mutect2, varscan2
- ATP11B | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV60026317; called by muse, mutect2, varscan2
- ATP11C | c.694A>G p.S232G | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100557530; called by muse, mutect2, varscan2
- ATP13A4 | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100710132; called by muse, mutect2
- ATP13A4 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100710133; called by muse, mutect2
- ATP13A4 | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 274/484 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as COSV55068521; called by muse, mutect2
- ATP13A5 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV100664812; called by muse, mutect2, varscan2
- ATP13A5 | c.1675-1G>T p.X559_splice | Splice Site (SNP) | VAF 46/263 reads (17%) | catalogued as COSV100664814, COSV60869073; called by muse, varscan2
- ATP1A1 | c.19del p.R7Vfs*29 | Frame Shift Del (DEL) | VAF 45/158 reads (28%) | catalogued as COSV55189682, COSV55192203; called by mutect2, pindel, varscan2
- ATP1A2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs779812635, COSV63402362, COSV63403685; called by muse, mutect2, varscan2
- ATP1A4 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV100927640, COSV63625395; called by muse, mutect2, varscan2
- ATP1A4 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV63625530; called by muse, mutect2, varscan2
- ATP1B1 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 40/120 reads (33%) | catalogued as COSV63178897; called by muse, mutect2, varscan2
- ATP1B2 | c.130T>G p.Y44D | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV51514851; called by muse, mutect2, varscan2
- ATP2A1 | c.2220C>A p.F740L | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV62868552; called by muse, mutect2, varscan2
- ATP2A3 | c.1751T>G p.F584C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59226363; called by muse, mutect2, varscan2
- ATP2B1 | c.2015C>T p.T672I | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV53804117; called by muse, mutect2, varscan2
- ATP2B3 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1557010446, CM156865, COSV54839891; called by muse, mutect2, varscan2
- ATP2B4 | c.648C>T p.Y216= | Splice Region (SNP) | VAF 51/123 reads (41%) | catalogued as rs748137308, COSV58174509; called by muse, mutect2, varscan2
- ATP2B4 | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV58174532; called by muse, mutect2, varscan2
- ATP2B4 | c.2176G>T p.E726* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as COSV58174561; called by muse, mutect2, varscan2
- ATP2C1 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 154/305 reads (50%) | catalogued as COSV60752844; called by muse, mutect2, varscan2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP4A | c.2995T>C p.W999R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV52865732; called by muse, mutect2, varscan2
- ATP5F1A | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs375873918; called by muse, mutect2, varscan2
- ATP5F1E | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); catalogued as rs138025844, COSV53885771; called by muse, mutect2, varscan2
- ATP6AP1 | c.289-2A>G p.X97_splice | Splice Site (SNP) | VAF 37/101 reads (37%) | catalogued as COSV62340889; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2472G>T p.K824N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV59472714; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100022753; called by muse, varscan2
- ATP6V0A4 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59472735; called by muse, mutect2, varscan2
- ATP6V0D2 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV53413197; called by muse, mutect2, varscan2
- ATP6V1B2 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99369263; called by muse, mutect2
- ATP6V1C2 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55357964; called by muse, mutect2, varscan2
- ATP6V1D | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs772067354, COSV53598836; called by muse, mutect2, varscan2
- ATP6V1E1 | c.530+2T>C p.X177_splice | Splice Site (SNP) | VAF 58/166 reads (35%) | catalogued as COSV53656998; called by muse, mutect2, varscan2
- ATP7A | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV58442977; called by muse, mutect2, varscan2
- ATP7A | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 53/300 reads (18%) | catalogued as COSV58442989; called by muse, mutect2, varscan2
- ATP7A | c.2446C>A p.Q816K | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as CM023882, COSV58443003; called by muse, mutect2, varscan2
- ATP7A | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM110857, COSV58443017; called by muse, mutect2, varscan2
- ATP7B | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV54435370, COSV99666591; called by muse, mutect2, varscan2
- ATP8A1 | c.2384T>C p.V795A | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100045216; called by muse, mutect2
- ATP8A2 | c.1115A>C p.N372T | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV54938043; called by muse, mutect2, varscan2
- ATP8A2 | c.2890C>A p.H964N | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV54938053, COSV99683033; called by muse, mutect2, varscan2
- ATP8B2 | c.809G>A p.R270Q (on ENST00000672630; = p.R237Q on NM_001005855.2) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1357697076, COSV59244805; called by muse, mutect2, varscan2
- ATP8B3 | c.3800G>T p.G1267V | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59540345; called by muse, mutect2, varscan2
- ATP8B4 | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 53/182 reads (29%) | catalogued as COSV52709677; called by muse, mutect2, varscan2
- ATP8B4 | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52709689; called by muse, mutect2, varscan2
- ATR | c.7777C>A p.L2593I | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV53808233; called by muse, mutect2, varscan2
- ATR | c.7219C>T p.R2407C | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746049210, COSV63384106; called by muse, mutect2, varscan2
- ATR | c.5656C>T p.R1886* | Nonsense Mutation (SNP) | VAF 45/149 reads (30%) | catalogued as rs141429029, COSV63389479; called by muse, mutect2, varscan2
- ATRAID | c.746G>A p.R249H (on ENST00000611786; = p.R136H on NM_016085.5) | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375386400; called by muse, mutect2, varscan2
- ATRN | c.3952C>T p.R1318* | Nonsense Mutation (SNP) | VAF 64/137 reads (47%) | catalogued as COSV53523748; called by muse, mutect2, varscan2
- ATRNL1 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs782775721, COSV61797510; called by muse, mutect2, varscan2
- ATRNL1 | c.2840G>T p.R947I | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100369542; called by muse, varscan2
- ATRNL1 | c.3420G>A p.S1140= | Splice Region (SNP) | VAF 48/118 reads (41%) | catalogued as rs776297873, COSV58074963, COSV58099812; called by muse, varscan2
- ATRX | c.6406G>A p.D2136N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as HM971898, COSV64871873; called by muse, mutect2, varscan2
- ATRX | c.6137C>A p.S2046Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64871881; called by muse, mutect2, varscan2
- ATRX | c.2541T>G p.F847L | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs782483240, COSV100970184; called by muse, varscan2
- ATRX | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV64882726, COSV64886159; called by muse, mutect2
- ATXN2 | c.1196A>G p.N399S (on ENST00000550104; = p.N239S on NM_002973.4) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as rs989467637, COSV66481420; called by muse, mutect2, varscan2
- ATXN7L3 | c.735G>A p.S245= (on ENST00000389384 / NM_001382309.1; = p.S252= on NM_001382308.1 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as rs181092765, COSV60228152; called by muse, mutect2, varscan2
- AUP1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV57816074; called by muse, mutect2, varscan2
- AUTS2 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV61384626; called by muse, mutect2, varscan2
- AUTS2 | c.2705A>G p.K902R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.041); catalogued as rs763718023, COSV61384634; called by mutect2, varscan2
- AVIL | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs549145073, COSV57680547; called by muse, mutect2, varscan2
- AVL9 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1357790661, COSV59464253; called by muse, mutect2, varscan2
- AVPR1B | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV65637725; called by muse, mutect2, varscan2
- AXDND1 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV62639913; called by muse, mutect2, varscan2
- AXDND1 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779483631, COSV100858262; called by muse, mutect2
- AZI2 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55423119; called by muse, mutect2, varscan2
- AZIN1 | c.134T>G p.L45R | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61479267; called by muse, mutect2, varscan2
- B3GNT2 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV100114059; called by muse, mutect2
- B3GNT5 | c.652T>G p.F218V | Missense Mutation (SNP) | VAF 138/232 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV58475410; called by muse, mutect2, varscan2
- B3GNT7 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55005871; called by muse, mutect2, varscan2
- B4GALNT1 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV62041381; called by muse, mutect2, varscan2
- BAAT | c.709G>T p.G237* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV52287277; called by muse, mutect2, varscan2
- BABAM2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775096236, COSV100567420; called by mutect2, varscan2
- BACE1 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100474866; called by muse, mutect2
- BACE2 | c.641T>C p.F214S | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57737551; called by muse, mutect2, varscan2
- BAG5 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 37/79 reads (47%) | catalogued as rs182208325, COSV54570184; called by muse, mutect2, varscan2
- BAIAP3 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs780577265, COSV50103566; called by muse, mutect2, varscan2
- BANF1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV56463297; called by muse, mutect2, varscan2
- BANK1 | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1280482723, COSV59838624, COSV59841698; called by muse, mutect2, varscan2
9,533 further variants in this file (7,326 protein-altering or splice-affecting, 2,035 silent, 172 other) are not listed here.
